Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A259, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A259-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):

ge: IF Race:

Specimen #:

Taken:
Received:
Reported:

SPECIMEN:

A: SENTINEL LYMPH NODE BIOPSY, LEFT
B: LEFT BREAST LUMPECTOMY

100-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9

hw 4/27/11

FINAL DIAGNOSIS:

- A. SENTINEL LYMPH NODE, DESIGNATED LEFT BREAST, BIOPSY:
- LYMPH NODES EXAMINED: 2
- LYMPH NODES POSITIVE FOR METASTASIS: 0
(EXAMINATION OF MULTIPLE SECTIONS STAINED WITH HEMATOXIN AND EOSIN AND BY IMMUNOHISTOCHEMISTRY FOR CYTOKERATIN)
- B. LEFT BREAST, LUMPECTOMY:
- TUMOR TYPE: INVASIVE DUCTAL CARCINOMA
- NOTTINGHAM GRADE: 2 (MODERATELY DIFFERENTIATED)
- NOTTINGHAM SCORE: 7 (Tubules= 3, Nuclei= 3, Mitoses= 1, mitotic count 4 per 10 HPF at 40x power)
- TUMOR SIZE (GREATEST DIMENSION): GREATEST DIMENSION 1.5 CM (MEASURED GROSSLY)
- TUMOR NECROSIS: ABSENT
- MICROCALCIFICATIONS: PRESENT IN DUCTAL CARCINOMA IN-SITU, INVASIVE CARCINOMA, AND BENIGN DUCTS
- VENOUS/LYMPHATIC INVASION: ABSENT
- MARGINS: NOT INVOLVED (BUT CLOSE:)
- DISTANCE OF INVASIVE TUMOR FROM NEAREST MARGIN: 0.95 MM FROM SUPERIOR MARGIN (B2)
- DISTANCE OF INTRADUCTAL CARCINOMA FROM NEAREST MARGIN: 1.1 MM FROM SUPERIOR MARGIN (B1)
- INTRADUCTAL COMPONENT:
DUCTAL CARCINOMA IN SITU WITH FOCAL NECROSIS, GRADE 2
COMPRISES LESS THAN 20% OF THE TUMOR
LOBULAR CARCINOMA IN SITU
- ESTROGEN RECEPTORS: POSITIVE
(REPORTED ON EARLIER CORE BIOPSY)
- PROGESTERONE RECEPTORS: POSITIVE
(REPORTED ON EARLIER CORE BIOPSY)
- HER 2 NEU by IHC: NEGATIVE (1+)
(REPORTED ON EARLIER CORE BIOPSY)
- PATHOLOGIC STAGE: pT1cN0(i-)MX

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

FINAL DIAGNOSIS (continued):

-ADDITIONAL PATHOLOGIC CHANGES:
ADENOSIS
CHANGES CONSISTENT WITH PRIOR BIOPSY

** Report Electronically Signed Out **

=====

CLINICAL DIAGNOSIS AND HISTORY:

left breast cancer

GROSS DESCRIPTION:

A. Received fresh labeled with the patient's name designated "SENTINEL LYMPH NODE BIOPSY LEFT BREAST" consists of a 4.0 x 3.0 x 1.0 cm irregular portion of soft tissue. Sectioning reveals two grey yellow fatty lymph nodes each measuring 1.5 x 1.0 x 0.3 cm in overall dimension. The specimen is entirely submitted as follows:

A1-A2: lymph node #1
A3-A4: lymph node #2
A5-A6: remaining adipose tissue. 6CFNS.

B. Received fresh with accompanying radiograph and embedded localization wire labeled with the patient's name designated "LEFT BREAST LUMPECTOMY" consists of an irregular portion of tan yellow soft tissue oriented with short stitch superior and long lateral. The specimen measures 9.5 cm medial to lateral, 6.5 cm superior to inferior, 2.5 cm anterior to posterior. The superior margin is focally disrupted. The specimen is inked as follows: superior blue, inferior green, medial red, lateral yellow, anterior orange, posterior black. Serial sections reveal a fairly well defined pink grey gritty mass measuring 1.5 x 1.2 x 1.0 cm in overall dimension. The mass comes to within 0.2 cm of the anterior margin and is located 1.0 cm from superior margin. The remainder of the cut surface is composed of markedly dense pink grey fibrous tissue with lobulated yellow tan adipose tissue. No additional lesions are identified. Sections are submitted as follows:

B1-B2: mass
B3: anterior margin
B4: normal appearing fibrous tissue

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

B5-B6: medial and posterior margin
B7-B8: superior margin
B9-B10: inferior margin
B11-B12: lateral margin. 12CFSS.

Source: NCI Genomic Data Commons file 36d4e83f-9351-43e0-b638-39a21dd45a4d (TCGA-A2-A259.33569E07-D7BF-491B-A352-CEEA81556800.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).